Gene-level copy-number profile of tumor specimen TCGA-78-7539-01A from TCGA case TCGA-78-7539, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 75.1 years (27,445 days).
Specimen TCGA-78-7539-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.9f0e8364-72fb-4d33-b403-6af6889c049e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-78-7539-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b88ca738-bf64-4069-a942-e72fd1ea0e4c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 10,255; copy number 3: 26,630; copy number 4: 14,413; copy number 5: 5,007; copy number 6: 1,610; copy number 7: 188; copy number 8: 712; copy number 9: 722; copy number 10: 244; copy number 11: 12; copy number 12: 15; copy number 15: 4; copy number 17: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-78-7539-01A-11D-2062-01): tumor purity 0.52, ploidy 3.49, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,904 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,565,654–162,868,815, 505 genes, copy number 9 (broad region; genes not listed).
- chr4:51,843,000–52,659,301, 12 genes, copy number 11 (within-gene range 3–11): DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1, RNU6-1252P, USP46.
- chr4:69,181,660–78,939,438, 193 genes, copy number 9–17 (broad region; genes not listed).
- chr4:99,816,827–110,293,573, 146 genes, copy number 7–9 (broad region; genes not listed).
- chr4:110,399,773–110,418,504, 2 genes, copy number 8: RPL7L1P13, ZNF969P.
- chr4:113,419,840–114,104,225, 7 genes, copy number 8: RN7SL184P, RNU1-138P, CAMK2D, AC111193.1, ARSJ, AC104779.1, AC093815.1.
- chr4:150,047,004–153,415,081, 62 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr4:153,710,160–153,760,024, 1 gene, copy number 10 (within-gene range 5–10): RNF175.
- chr4:153,780,591–157,201,668, 62 genes, copy number 10 (broad region; genes not listed).
- chr4:157,204,462–157,204,855, 1 gene, copy number 10: AC112240.1.
- chr5:58,198–29,396,095, 444 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr11:83,386,988–85,682,908, 19 genes, copy number 8–12: AP000446.2, DLG2, DLG2-AS2, AP002370.1, LDHAL6DP, HNRNPA1P72, AP000852.1, AP001825.1, AP001825.2, AP001825.3, AP000857.2, AP000857.1, HNRNPCP6, AP002803.1, AP003035.1, RNU6-1292P, TMEM126B, TMEM126A, CREBZF.
- chr11:86,703,099–87,566,421, 21 genes, copy number 7: AP003059.1, AP003059.2, PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P, AP001528.1, AP001528.2, FZD4, FZD4-DT, HNRNPCP8, TMEM135, XIAPP2, AP002967.1, AP001102.1, AP000811.1, PSMA2P1, AP003497.1, AP003497.2, AP001784.1.
- chr11:90,193,614–90,226,538, 3 genes, copy number 7: AP000648.4, CHORDC1, AP002364.1.
- chr11:90,282,560–90,284,172, 1 gene, copy number 7: TUBAP2.
- chr11:92,336,032–107,928,293, 234 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr14:30,437,992–39,432,500, 175 genes, copy number 7–15 (broad region; genes not listed).
- chr14:40,630,006–42,989,483, 16 genes, copy number 8 (within-gene range 5–8): AL390800.1, LINC02315, AL391516.1, AL356596.1, AL121821.3, AL121821.2, AL121821.1, LRFN5, FKBP1BP1, AL445074.1, AL442163.1, AL450442.1, AL442163.2, AL442163.3, YWHAQP1, AL163153.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
